Somatic mutation profile of tumor specimen TCGA-HT-7882-01A (aliquot TCGA-HT-7882-01A-11D-2395-08) from TCGA case TCGA-HT-7882, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 66.9 years (24,450 days).
Specimen TCGA-HT-7882-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c37df9e-30ff-4f27-86ab-77ec3e6f1d86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7882-10A (Blood Derived Normal), aliquot TCGA-HT-7882-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4b2c4ba7-48fd-475a-baa1-814ee93001b7

The open-access MAF lists 49 somatic variants for this specimen: 34 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 14, Splice Site 2, Nonsense Mutation 2, In Frame Del 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASS1 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.781); catalogued as rs770944877, CM031623, COSV61689977; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PDGFRA | c.704G>A p.C235Y | Missense Mutation (SNP) | VAF 542/676 reads (80%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57264163, COSV57266901, COSV57267810; called by muse, mutect2, varscan2
- ASZ1 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 25/187 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as rs113501399, COSV52914600; called by muse, mutect2, varscan2
- ATP10A | c.2113T>C p.Y705H | Missense Mutation (SNP) | VAF 22/111 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.009); catalogued as COSV63520226; called by muse, mutect2, varscan2
- B3GNT5 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 19/101 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); catalogued as rs747782074, COSV58476439; called by muse, mutect2, varscan2
- CDC20B | c.798C>A p.N266K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV57054451; called by muse, mutect2, varscan2
- CEP97 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1235438627, COSV59125883; called by muse, mutect2, varscan2
- CFH | c.3605A>T p.K1202I | Missense Mutation (SNP) | VAF 17/107 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.28); catalogued as COSV66410621; called by muse, mutect2, varscan2
- DYNC2H1 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs561232842, COSV62086954; ClinVar: likely benign; called by muse, mutect2, varscan2
- EFCAB1 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as rs201706002, COSV100030541, COSV50617834; called by muse, mutect2, varscan2
- EVPL | c.5511_5513del p.N1837del | In Frame Del (DEL) | VAF 24/216 reads (11%) | catalogued as rs778875284; called by pindel, varscan2
- FBXW10 | c.2148_2151del p.K718Vfs*18 | Frame Shift Del (DEL) | VAF 27/191 reads (14%) | catalogued as rs778552789; called by mutect2, pindel, varscan2
- HS3ST6 | c.614G>A p.R205H | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs534111598, COSV53535685; called by muse, mutect2, varscan2
- IGHV3-53 | c.326C>T p.T109M | Missense Mutation (SNP) | VAF 29/260 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.557); catalogued as rs781870379; called by muse, mutect2, varscan2
- KDM7A | c.1365T>G p.I455M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV50093251; called by muse, mutect2, varscan2
- LPO | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200102644, COSV51860132; called by muse, mutect2, varscan2
- MADD | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753381527, COSV60619910; called by muse, mutect2, varscan2
- MKI67 | c.7307A>G p.D2436G | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64075469; called by muse, mutect2, varscan2
- NPAP1 | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.104); catalogued as COSV61508803, COSV61510946; called by muse, mutect2, varscan2
- OR5L1 | c.117G>T p.L39F | Missense Mutation (SNP) | VAF 34/259 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs1302393183, COSV100450187, COSV61734611; called by muse, varscan2
- PCDH11X | c.2672C>A p.T891N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.026); catalogued as COSV53484026; called by muse, mutect2, varscan2
- PDE7B | c.731A>G p.N244S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.173); catalogued as COSV57502183; called by muse, mutect2, varscan2
- POTEE | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.556); catalogued as rs761896133, COSV58236334; called by muse, mutect2, varscan2
- PPP1R3A | c.3164C>T p.P1055L | Missense Mutation (SNP) | VAF 18/175 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.873); catalogued as COSV52886805; called by muse, mutect2, varscan2
- PRSS35 | c.793C>T p.R265* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as rs773975931, COSV63800668; called by muse, mutect2, varscan2
- SAMD3 | c.698G>A p.R233Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); catalogued as rs774559077, COSV63713170; called by muse, mutect2, varscan2
- SLCO4C1 | c.1811+1G>T p.X604_splice | Splice Site (SNP) | VAF 9/59 reads (15%) | catalogued as rs768539783, COSV60517739; called by muse, mutect2, varscan2
- SRSF11 | c.1023-1G>C p.X341_splice | Splice Site (SNP) | VAF 5/45 reads (11%) | catalogued as COSV63937352; called by muse, mutect2, varscan2
- SURF2 | c.551C>T p.T184M | Missense Mutation (SNP) | VAF 4/61 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs587600299, COSV64332513; called by muse, mutect2
- TAS2R40 | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 12/128 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs374345239; called by muse, mutect2
- TET2 | c.2795A>G p.D932G | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV54399356, COSV54420868; called by muse, mutect2, varscan2
- XKR7 | c.827C>T p.T276M | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs752458312, COSV73813103; called by muse, varscan2
- NAV3 | c.1768_1788del p.Q590_S596del | In Frame Del (DEL) | VAF 17/139 reads (12%) | called by mutect2, pindel
- OSBPL3 | c.1071G>C p.E357D | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- AKAP4 | c.1140C>T p.S380= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs140947270, COSV62074614; called by muse, mutect2, varscan2
- BRF1 | c.1116C>T p.A372= | Silent (SNP) | VAF 4/27 reads (15%) | catalogued as rs1342446243, COSV59270891; called by muse, mutect2
- CCKBR | c.828C>T p.N276= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as rs749921079, COSV58102405; called by muse, mutect2, varscan2
- DPP10 | c.816G>A p.A272= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as rs573090640, COSV59691032; called by muse, mutect2, varscan2
- FMO3 | c.654C>G p.S218= | Silent (SNP) | VAF 13/120 reads (11%) | catalogued as COSV63007846; called by muse, mutect2
- GLIS1 | c.861G>A p.T287= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as rs376177881; called by muse, mutect2, varscan2
- HCK | c.519C>T p.S173= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs900583875, COSV52944829; called by muse, mutect2
- KDM5B | c.3699G>A p.L1233= | Silent (SNP) | VAF 15/87 reads (17%) | catalogued as COSV52509960; called by muse, mutect2, varscan2
- NPAP1 | c.78T>A p.A26= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV61508799; called by muse, mutect2, varscan2
- OR13G1 | c.852G>A p.P284= | Silent (SNP) | VAF 17/106 reads (16%) | catalogued as rs762243934, COSV62943598, COSV62943875, COSV62944685; called by muse, mutect2, varscan2
- TAS1R2 | c.831C>T p.P277= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs201166508, COSV64744347; called by muse, mutect2, varscan2
- TEAD3 | c.570G>A p.P190= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as rs1325637618, COSV58817509; called by muse, mutect2
- TSBP1 | c.1047G>A p.T349= (on ENST00000617061; = p.T354= on NM_006781.5) | Silent (SNP) | VAF 22/150 reads (15%) | catalogued as rs760645031, COSV66659958; called by muse, mutect2, varscan2
- ZNF536 | c.3555C>T p.T1185= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs373198343, COSV62830997; called by mutect2, varscan2
- OBSCN | c.11659+4934G>A | Intron (SNP) | VAF 10/69 reads (14%) | catalogued as rs573702782, COSV99476137; called by muse, mutect2, varscan2
